Somatic mutation profile of tumor specimen MP2PRT-PATKVV-TMP1-A (aliquot MP2PRT-PATKVV-TMP1-A-1-0-D-A80K-36) from MP2PRT case MP2PRT-PATKVV, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 2.8 years (1,014 days).
Specimen MP2PRT-PATKVV-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 599fa461-c33c-4c10-903e-cc52e6c508ae.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PATKVV-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PATKVV-NB1-A-1-0-D-A80K-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/adcdecea-f6d0-4306-b115-458fc5d5eaaa

The open-access MAF lists 9 somatic variants for this specimen: 6 protein-altering or splice-affecting, 2 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 2, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ADAMTS5 | c.1741C>T p.R581C | Missense Mutation (SNP) | VAF 353/541 reads (65%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs200886341; called by muse, mutect2, varscan2
- AGRN | c.1930G>A p.E644K | Missense Mutation (SNP) | VAF 230/439 reads (52%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.953); catalogued as rs767435056, COSV65069876; called by muse, mutect2, varscan2
- ATP6V0A4 | c.638C>T p.T213M | Missense Mutation (SNP) | VAF 27/279 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs539497353, COSV59475611; called by muse, mutect2
- ZBTB17 | c.2241C>A p.F747L | Missense Mutation (SNP) | VAF 203/443 reads (46%) | SIFT deleterious (0.02); PolyPhen benign (0.097); catalogued as COSV100998998; called by muse, mutect2, varscan2
- IGHV3-30 | chr14:106335074 ACTGTGTCTT>CCCCCGA | Missense Mutation (DEL) | VAF 61/281 reads (22%) | called by pindel, varscan2*
- IGKV1OR2-108 | chr2:113406870 ATTCACAGTGT>CTCTC | Missense Mutation (DEL) | VAF 56/62 reads (90%) | called by pindel, varscan2*
- F11 | c.1164C>T p.I388= | Silent (SNP) | VAF 150/301 reads (50%) | catalogued as rs1165954112, COSV53001317; called by muse, mutect2, varscan2
- GNAT1 | c.285A>G p.A95= | Silent (SNP) | VAF 92/226 reads (41%) | called by muse, mutect2, varscan2
- BEGAIN | c.15-3842G>A | Intron (SNP) | VAF 130/314 reads (41%) | catalogued as rs893979687; called by muse, mutect2, varscan2
